Gene-level copy-number profile of tumor specimen TCGA-FD-A5BR-01A from TCGA case TCGA-FD-A5BR, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 57.4 years (20,964 days).
Specimen TCGA-FD-A5BR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.c058de01-4f89-44dc-97b1-ac7027e9d5a1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FD-A5BR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/57176913-a207-48e0-91f8-3338e7852f9b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 76; copy number 1: 10,816; copy number 2: 42,254; copy number 3: 3,185; copy number 4: 3,488; copy number 5: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FD-A5BR-01A-11D-A26L-01): tumor purity 0.44, ploidy 3.83, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 76 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,999,509–24,592,104, 73 genes (broad region; genes not listed).
- chr9:25,088,811–25,678,440, 3 genes: RN7SKP120, AL353730.1, TUSC1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:24,905,469–24,905,735, 1 gene, copy number 5: RMRPP5.

Autosomal genes at a single copy (total copy number 1): 8,401. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
